Somatic mutation profile of tumor specimen TCGA-FI-A2EU-01A (aliquot TCGA-FI-A2EU-01A-11D-A17D-09) from TCGA case TCGA-FI-A2EU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-FI-A2EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e63dbcab-048d-4b7f-a299-ddc0ced76e5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2EU-10A (Blood Derived Normal), aliquot TCGA-FI-A2EU-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b482115e-be6c-434e-9212-aadefd61be49

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 28/29 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 76/146 reads (52%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, varscan2
- ADAMTS17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765090779, COSV51472944; called by mutect2, varscan2
- AMER1 | c.2820G>A p.W940* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100365966, COSV57654932; called by muse, mutect2, varscan2
- ANKAR | c.3912T>G p.I1304M | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99854163; called by muse, mutect2, varscan2
- ANKRD11 | c.3970T>G p.S1324A | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99969148; called by muse, mutect2, varscan2
- ARHGAP35 | c.183T>G p.S61R | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101350946; called by muse, mutect2, varscan2
- CCNYL1 | c.397G>C p.V133L (on ENST00000295414 / NM_001330218.2; = p.V63L on NM_152523.2) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV99775850; called by muse, mutect2, varscan2
- CCT8L2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs755816031, COSV100742661; called by muse, mutect2, varscan2
- CDC42BPB | c.4079C>T p.T1360M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs528394229, COSV100775411; called by muse, mutect2, varscan2
- CDX2 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs376483726, COSV101122644, COSV101122645; called by muse, mutect2, varscan2
- COL8A1 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as COSV99657660; called by muse, mutect2, varscan2
- COPA | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 70/151 reads (46%) | catalogued as rs559780460, COSV54107809, COSV99615450; called by muse, mutect2, varscan2
- CRACD | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1287374834, COSV99948315; called by muse, mutect2, varscan2
- DCLRE1C | c.770G>A p.R257Q (on ENST00000378278 / NM_001350965.2; = p.R142Q on NM_022487.4) | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs762842349, COSV100739799; called by muse, mutect2, varscan2
- DMP1 | c.1239C>A p.N413K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99218685; called by muse, mutect2, varscan2
- FAT4 | c.3820G>C p.D1274H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272299; called by muse, mutect2, varscan2
- FLG | c.11047G>A p.G3683R | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs778053862, COSV100911516; called by muse, mutect2, varscan2
- GPSM2 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.069); catalogued as COSV51442474, COSV99915221; called by muse, mutect2, varscan2
- IQCE | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 61/115 reads (53%) | catalogued as COSV100383372; called by muse, mutect2, varscan2
- ISM2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99376607; called by muse, mutect2, varscan2
- KATNB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as rs529376681, COSV65552015; called by muse, mutect2, varscan2
- KCNC4 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1205359417, COSV100873610; called by muse, mutect2
- KCNS1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs573545376, COSV60260403; called by muse, mutect2, varscan2
- KDM2B | c.576+1G>T p.X192_splice | Splice Site (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100997388; called by muse, mutect2, varscan2
- KRT33B | c.1005G>C p.Q335H | Missense Mutation (SNP) | VAF 86/97 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99290604; called by muse, mutect2, varscan2
- LCT | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99929350; called by muse, mutect2, varscan2
- LRP2 | c.7294A>G p.R2432G | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99788120; called by muse, mutect2, varscan2
- NCOR1 | c.6341G>C p.R2114T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99249546; called by muse, mutect2, varscan2
- NRDC | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV100703345, COSV61406082; called by muse, mutect2, varscan2
- PHKA2 | c.2272G>A p.V758M | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs1431642322, COSV101176997; called by muse, mutect2
- PLA2G12B | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.061); catalogued as rs752897409, COSV100888001; called by muse, mutect2, varscan2
- PLD2 | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV99562311; called by muse, mutect2, varscan2
- PNKD | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs759669801, COSV51230865; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRG4 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs1251639441, COSV100825745; called by muse, mutect2
- RELT | c.1270A>G p.S424G | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.066); catalogued as COSV99292859; called by muse, mutect2
- SAMD8 | c.570C>G p.F190L | Missense Mutation (SNP) | VAF 57/452 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV101014041; called by muse, mutect2, varscan2
- SDK1 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207386003, COSV101269319; called by muse, mutect2, varscan2
- SPOP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV61652701; called by muse, mutect2, varscan2
- TGM2 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV100821600; called by muse, mutect2, varscan2
- UGT1A3 | c.595A>T p.T199S | Missense Mutation (SNP) | VAF 107/228 reads (47%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); catalogued as COSV100530196; called by muse, mutect2, varscan2
- WDR47 | c.1997G>A p.C666Y (on ENST00000369962 / NM_001142551.2; = p.C667Y on NM_014969.5) | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100728338; called by muse, mutect2, varscan2
- WDR90 | c.5237C>G p.P1746R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99553280; called by muse, mutect2
- ZNF573 | c.1825C>T p.P609S (on ENST00000536220 / NM_001172692.1; = p.P551S on NM_152360.3) | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100265595; called by muse, mutect2, varscan2
- ANKRD52 | c.2817del p.K939Nfs*5 | Frame Shift Del (DEL) | VAF 62/137 reads (45%) | called by mutect2, pindel, varscan2
- DOCK4 | c.986_987del p.T329Rfs*3 | Frame Shift Del (DEL) | VAF 89/153 reads (58%) | called by pindel, varscan2
- NAA15 | c.1841dup p.N614Kfs*17 | Frame Shift Ins (INS) | VAF 28/64 reads (44%) | called by mutect2, varscan2
- TP53 | c.666_667del p.P223* | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | called by pindel, varscan2
- ADAM30 | c.432C>T p.Y144= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs774240614, COSV101023837; called by muse, mutect2, varscan2
- AMIGO3 | c.681C>G p.L227= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV100246553; called by muse, mutect2, varscan2
- DNAJC27 | c.510C>T p.G170= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs138836610; called by muse, mutect2, varscan2
- DSC1 | c.2646C>A p.P882= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV99937572; called by muse, mutect2, varscan2
- GPR20 | c.87G>A p.G29= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100897307; called by muse, mutect2, varscan2
- KIAA1210 | c.2778A>G p.Q926= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV101274088; called by muse, mutect2, varscan2
- LIPA | c.453C>T p.D151= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as COSV99260232; called by muse, mutect2, varscan2
- MPEG1 | c.2016C>T p.I672= | Silent (SNP) | VAF 9/182 reads (5%) | catalogued as COSV57092628; called by muse, mutect2
- OR10G8 | c.735C>T p.I245= | Silent (SNP) | VAF 233/258 reads (90%) | catalogued as rs748588345, COSV70908219; called by muse, mutect2, varscan2
- ZFYVE26 | c.1905G>A p.L635= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as COSV100720364; called by muse, mutect2, varscan2
- ZNF142 | c.1671A>G p.L557= (on ENST00000411696 / NM_001379660.1; = p.L357= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs1438711608, COSV101376930; called by muse, mutect2, varscan2
- MRPS17P9 | n.143C>T | RNA (SNP) | VAF 26/50 reads (52%) | catalogued as rs1460095577; called by muse, mutect2, varscan2
